Somatic mutation profile of tumor specimen TCGA-28-2502-01B (aliquot TCGA-28-2502-01B-01D-1494-08) from TCGA case TCGA-28-2502, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.2 years (23,807 days).
Specimen TCGA-28-2502-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64ddff72-37c7-45d2-b8f1-8c6bca7cf166.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-2502-10A (Blood Derived Normal), aliquot TCGA-28-2502-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27aa82e2-0a8c-43c0-bc89-9f071cce278c

The open-access MAF lists 55 somatic variants for this specimen: 36 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 18, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F22 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs776275777, COSV54107182, COSV54109072; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5911G>A p.A1971T | Missense Mutation (SNP) | VAF 23/156 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1057524049, COSV63872841, COSV63877454; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 25/82 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64295132, COSV64296674, COSV64298389; called by muse, mutect2, varscan2
- ABCA10 | c.541G>T p.G181* | Nonsense Mutation (SNP) | VAF 57/285 reads (20%) | catalogued as COSV52226483; called by muse, mutect2, varscan2
- ADAM30 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as rs200088734, COSV65561660; called by muse, mutect2, varscan2
- ADGRF5 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV51937387; called by muse, mutect2, varscan2
- ANKS6 | c.2034A>T p.L678F | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62051199; called by muse, mutect2, varscan2
- ASAP1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs760787804, COSV63051915; called by muse, mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 17/87 reads (20%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2, varscan2
- C1QC | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs769724909, COSV65889552; called by muse, mutect2, varscan2
- CDH18 | c.1288T>A p.F430I | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.13); catalogued as COSV56942840, COSV56967332; called by muse, mutect2, varscan2
- CLCN7 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs775085622, COSV51970948; called by muse, varscan2
- COL27A1 | c.3064G>A p.V1022M | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs141446597; called by muse, mutect2, varscan2
- DNAI3 | c.1351C>G p.P451A | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV54004425; called by muse, mutect2, varscan2
- EXD1 | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59255419; called by muse, mutect2, varscan2
- FBLN2 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs1272556761, COSV55480844; called by muse, mutect2, varscan2
- FLG | c.10304G>A p.R3435H | Missense Mutation (SNP) | VAF 180/715 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs576274425, COSV64241308; called by muse, mutect2, varscan2
- H2BC1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.999); catalogued as rs766504742, COSV51237812; called by muse, mutect2, varscan2
- IFNGR2 | c.488T>C p.F163S | Missense Mutation (SNP) | VAF 154/687 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51640318; called by muse, mutect2, varscan2
- INTS12 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 94/391 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV60862962; called by muse, mutect2, varscan2
- MEI1 | c.3580G>C p.G1194R | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV55905222; called by muse, mutect2, varscan2
- MEP1A | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57921538; called by muse, mutect2, varscan2
- NF1 | c.499_502del p.C167Qfs*10 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | catalogued as rs786201874; called by pindel, varscan2
- OR2A42 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs764203936, COSV66955789; called by muse, mutect2, varscan2
- RYR3 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 34/120 reads (28%) | catalogued as rs370675640; called by muse, varscan2
- SCN10A | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 79/336 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1131691525, COSV71862254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.3800T>C p.V1267A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV67380274; called by muse, mutect2
- SETD1A | c.1931C>G p.P644R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52690028, COSV52690414; called by muse, mutect2, varscan2
- SPOCD1 | c.1346G>A p.R449K | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57098061; called by muse, mutect2, varscan2
- SYNE1 | c.22846C>T p.R7616W (on ENST00000367255 / NM_182961.4; = p.R7545W on NM_033071.3) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200236760; called by muse, mutect2, varscan2
- TMEM184B | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as rs1182803874, COSV62673332; called by muse, mutect2, varscan2
- TRIM10 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as rs748972009, COSV64999571; called by muse, mutect2
- UGT2B28 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV59433325; called by muse, mutect2, varscan2
- UNC93A | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs202053224, COSV57809723; called by muse, mutect2, varscan2
- ZNF831 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1443345757, COSV64042957; called by muse, mutect2, varscan2
- DEPDC7 | c.532_533del p.L178Efs*22 (on ENST00000241051 / NM_001077242.2; = p.L169Efs*22 on NM_139160.2) | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1506C>T p.N502= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs1172160153; called by muse, mutect2, varscan2
- ADGRG7 | c.1257T>C p.A419= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV56299091; called by muse, mutect2, varscan2
- CASR | c.2100C>T p.I700= (on ENST00000490131; = p.I777= on NM_000388.4) | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs760608351, COSV56139438; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC105 | c.1230G>A p.P410= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as rs773132972, COSV52964807; called by muse, mutect2, varscan2
- CPN1 | c.300G>A p.S100= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as rs770069005, COSV64942566; called by muse, mutect2, varscan2
- DMPK | c.1269G>A p.L423= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV52180288; called by muse, mutect2
- FAM47B | c.1161G>A p.P387= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs758718114, COSV61455581; called by muse, mutect2, varscan2
- FFAR2 | c.370C>T p.L124= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV55832863; called by muse, mutect2, varscan2
- GALNT8 | c.1011A>C p.A337= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs750840473; called by muse, mutect2
- KDM5A | c.3666G>A p.R1222= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV66994634; called by muse, mutect2, varscan2
- LPAR3 | c.330C>T p.D110= | Silent (SNP) | VAF 124/437 reads (28%) | catalogued as COSV65454359; called by muse, mutect2, varscan2
- MAP1B | c.1650A>G p.K550= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV57102968; called by muse, mutect2, varscan2
- MICB | c.543C>T p.R181= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs761060976, COSV52855261; called by muse, mutect2, varscan2
- MUC17 | c.13197C>T p.V4399= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs762504748, COSV60296322; called by muse, mutect2, varscan2
- MYH9 | c.2968C>T p.L990= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV53386596, COSV53390200; called by muse, mutect2, varscan2
- NOBOX | c.453C>T p.T151= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs780060226, COSV56196136; called by muse, mutect2, varscan2
- PANX2 | c.1860C>T p.N620= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs145485598, COSV50303634; called by muse, mutect2, varscan2
- ZNF556 | c.858G>A p.P286= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as rs377206346; called by muse, mutect2, varscan2
- ZFHX3 | c.-533+99G>A | Intron (SNP) | VAF 22/103 reads (21%) | catalogued as rs375757471; called by muse, mutect2, varscan2
